Somatic mutation profile of tumor specimen C3L-02604-01 (aliquot CPT0161770007) from CPTAC case C3L-02604, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 84.9 years (31,007 days).
Specimen C3L-02604-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 164ce499-3590-48cf-810c-dc5ca6e80232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02604-31 (Blood Derived Normal), aliquot CPT0162550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd05f89b-94b7-4de3-8f8e-704b5608ae1d

The open-access MAF lists 100 somatic variants for this specimen: 68 protein-altering or splice-affecting, 19 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Nonsense Mutation 6, Intron 4, 3'UTR 4, 5'UTR 3, Splice Region 2, Frame Shift Del 2, RNA 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 144/405 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 55/257 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP4A | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1483554588; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 147/597 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50056804; called by muse, mutect2, varscan2
- CDH10 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 142/637 reads (22%) | catalogued as COSV100050671; called by muse, mutect2, varscan2
- CLDN17 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs773823219, COSV54522581, COSV99729023; called by muse, mutect2, varscan2
- COL1A1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1567764128; ClinVar: uncertain significance; called by muse, mutect2
- CTAG2 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 103/694 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs1252217340; called by muse, mutect2, varscan2
- DDX11 | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 267/822 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs748906306, COSV52501136; called by muse, mutect2, varscan2
- DNAH5 | c.7544C>T p.T2515M | Missense Mutation (SNP) | VAF 135/545 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV54224881; called by muse, mutect2, varscan2
- DNAJB5 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 341/1002 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.466); catalogued as rs1341306176, COSV100257705; called by muse, varscan2
- DRAXIN | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 102/348 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.361); catalogued as rs762451052; called by muse, mutect2, varscan2
- FBN3 | c.4696G>A p.E1566K | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs765122699, COSV54469893; called by muse, mutect2, varscan2
- FKBP1C | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 177/792 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771238719; called by muse, mutect2, varscan2
- FYN | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 89/291 reads (31%) | catalogued as COSV57619557; called by muse, mutect2, varscan2
- GLP1R | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 101/396 reads (26%) | catalogued as rs763103077, COSV100952773; called by muse, mutect2, varscan2
- IGHA1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 275/1905 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1286596126; called by muse, mutect2, varscan2
- ITIH4 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 127/547 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201445354; called by muse, mutect2, varscan2
- LINC01036 | n.149C>T | Splice Region (SNP) | VAF 70/279 reads (25%) | catalogued as rs764508334; called by muse, mutect2, varscan2
- LONP1 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776606648; called by muse, mutect2, varscan2
- LRRC37A3 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1203875884; called by mutect2, varscan2
- LZTR1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769001939, COSV53145056; called by muse, mutect2, varscan2
- MAG | c.1388C>A p.S463* | Nonsense Mutation (SNP) | VAF 187/638 reads (29%) | catalogued as COSV62702024; called by muse, mutect2, varscan2
- MAPK3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 202/1143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1315743155; called by muse, mutect2, varscan2
- MRC1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 216/977 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs782693726; called by muse, mutect2, varscan2
- NFIA | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs761025450, COSV63607764; called by muse, mutect2, varscan2
- NFIC | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs529235700, COSV59417612; called by muse, mutect2, varscan2
- NFKBIZ | c.2110C>G p.R704G | Missense Mutation (SNP) | VAF 89/416 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100396872; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.290C>T p.A97V (on ENST00000259318 / NM_001136562.3; = p.A328V on NM_007203.5) | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs147894013; called by muse, mutect2, varscan2
- PARD3B | c.3383G>A p.R1128H (on ENST00000406610 / NM_001302769.2; = p.R1059H on NM_057177.7) | Missense Mutation (SNP) | VAF 94/336 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs200129953; called by muse, mutect2, varscan2
- PCDHA4 | c.2294C>A p.P765H | Missense Mutation (SNP) | VAF 20/647 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV63540017; called by muse, mutect2
- PDE1B | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs143206355, COSV54490043, COSV99226542; called by muse, mutect2, varscan2
- PLXDC1 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.545); catalogued as rs1267442125; called by muse, mutect2, varscan2
- PSAPL1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 93/398 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs763107725; called by muse, mutect2, varscan2
- PXDNL | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760527870, COSV62488380; called by muse, mutect2, varscan2
- SBSN | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 239/913 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.597); catalogued as rs767855118; called by muse, mutect2, varscan2
- SHROOM4 | c.2964G>T p.M988I | Missense Mutation (SNP) | VAF 113/523 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56795761; called by muse, mutect2, varscan2
- TAF1L | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 174/519 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs145899352; called by muse, mutect2, varscan2
- TAF5L | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 90/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs762046097, COSV51080829; called by muse, mutect2, varscan2
- TFAP2C | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs775607231, COSV104389725; called by muse, mutect2, varscan2
- TGDS | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.916); catalogued as COSV54300627; called by muse, mutect2, varscan2
- TP53 | c.459del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 121/391 reads (31%) | catalogued as COSV52700360, COSV52751929; called by mutect2, pindel, varscan2
- TPO | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 190/811 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs748124213, COSV61095654; called by muse, mutect2, varscan2
- TPTE | c.1321G>T p.V441F (on ENST00000618007 / NM_199261.4; = p.V423F on NM_199259.4) | Missense Mutation (SNP) | VAF 44/568 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as rs757127690; called by muse, mutect2
- AASS | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 277/1168 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ABLIM1 | c.378A>G p.K126= | Splice Region (SNP) | VAF 278/1319 reads (21%) | called by muse, mutect2, varscan2
- C10orf71 | c.4176C>A p.C1392* | Nonsense Mutation (SNP) | VAF 188/729 reads (26%) | called by muse, mutect2, varscan2
- CATSPER1 | c.1940T>A p.I647N | Missense Mutation (SNP) | VAF 166/751 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAVIN1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 138/857 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CRB2 | c.793T>C p.C265R | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EML2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTF3C3 | c.2067C>G p.I689M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, varscan2
- HIF1A | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRIT2 | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 84/348 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LTBP4 | c.2111G>A p.G704D (on ENST00000308370 / NM_001042544.1; = p.G667D on NM_003573.2) | Missense Mutation (SNP) | VAF 198/802 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MICB | c.1151A>C p.*384Sext*26 | Nonstop Mutation (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2
- NPC1L1 | c.2813_2814del p.T938Rfs*4 | Frame Shift Del (DEL) | VAF 75/366 reads (20%) | called by pindel, varscan2
- PPFIA4 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAX | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 158/475 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- REPS2 | c.1209+1_1209+4dup | Frame Shift Ins (INS) | VAF 45/249 reads (18%) | called by mutect2, pindel, varscan2
- RNF43 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- SCUBE1 | c.2501G>T p.R834L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1B | c.5705G>A p.R1902H | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA5 | c.2450A>G p.N817S | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAV17 | c.127T>C p.C43R | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H6 | c.1325A>G p.H442R | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ZNF491 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF697 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 112/453 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- AP000812.4 | c.189G>A p.T63= | Silent (SNP) | VAF 96/412 reads (23%) | catalogued as rs556093010, COSV53825266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf71 | c.888C>T p.T296= | Silent (SNP) | VAF 71/270 reads (26%) | catalogued as rs372950100; called by muse, mutect2, varscan2
- CLDN34 | c.81G>A p.T27= | Silent (SNP) | VAF 95/409 reads (23%) | catalogued as rs1035174605; called by muse, mutect2, varscan2
- CTBP2 | c.441G>T p.R147= | Silent (SNP) | VAF 178/982 reads (18%) | called by muse, mutect2, varscan2
- DNAH9 | c.9798C>T p.C3266= | Silent (SNP) | VAF 144/510 reads (28%) | called by muse, mutect2, varscan2
- FN1 | c.3456C>T p.T1152= | Silent (SNP) | VAF 152/622 reads (24%) | catalogued as rs762269962; called by muse, mutect2, varscan2
- HROB | c.531A>T p.G177= | Silent (SNP) | VAF 56/342 reads (16%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.537C>T p.R179= | Silent (SNP) | VAF 171/531 reads (32%) | catalogued as COSV99404235; called by muse, mutect2, varscan2
- LAMA5 | c.7113C>T p.R2371= | Silent (SNP) | VAF 154/644 reads (24%) | catalogued as rs111275179, COSV99442975; called by muse, mutect2, varscan2
- NBPF4 | c.1431C>T p.T477= | Silent (SNP) | VAF 91/635 reads (14%) | catalogued as rs1228536915; called by muse, mutect2, varscan2
- PCDHGA9 | c.1854G>A p.S618= | Silent (SNP) | VAF 189/766 reads (25%) | catalogued as rs774487660; called by muse, mutect2, varscan2
- PDE6B | c.306C>T p.G102= | Silent (SNP) | VAF 61/267 reads (23%) | catalogued as rs201939549, COSV55328837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG1 | c.2385C>T p.D795= | Silent (SNP) | VAF 84/306 reads (27%) | catalogued as rs140164486; called by muse, mutect2, varscan2
- PPP1R13B | c.1740C>T p.Y580= | Silent (SNP) | VAF 132/504 reads (26%) | called by muse, mutect2, varscan2
- PTPRT | c.3024C>T p.Y1008= | Silent (SNP) | VAF 101/480 reads (21%) | catalogued as rs369837092; called by muse, mutect2, varscan2
- RFPL4A | c.444C>T p.S148= | Silent (SNP) | VAF 140/1124 reads (12%) | catalogued as rs769869192; called by muse, mutect2, varscan2
- SLC4A1 | c.1824C>T p.F608= | Silent (SNP) | VAF 72/298 reads (24%) | catalogued as rs751967295, COSV99292966; called by muse, mutect2, varscan2
- SLC7A2 | c.945G>A p.P315= (on ENST00000494857 / NM_001370338.1; = p.P355= on NM_003046.6) | Silent (SNP) | VAF 231/917 reads (25%) | catalogued as rs141741899; called by muse, mutect2, varscan2
- SPO11 | c.297G>A p.K99= | Silent (SNP) | VAF 68/330 reads (21%) | called by muse, mutect2, varscan2
- AC092118.1 | n.1106C>T | RNA (SNP) | VAF 106/431 reads (25%) | called by muse, mutect2, varscan2
- CISD2 | c.*25C>T | 3'UTR (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- COL20A1 | c.3295-170A>C | Intron (SNP) | VAF 116/525 reads (22%) | called by muse, mutect2, varscan2
- DDX41 | c.139-26T>G | Intron (SNP) | VAF 171/581 reads (29%) | called by muse, mutect2, varscan2
- DYSF | c.4410+7146G>A | Intron (SNP) | VAF 95/477 reads (20%) | catalogued as rs766512164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.*12C>T | 3'UTR (SNP) | VAF 120/364 reads (33%) | catalogued as rs749023152; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129665G>A | Intron (SNP) | VAF 195/787 reads (25%) | called by muse, mutect2, varscan2
- LINC02649 | n.471T>C | RNA (SNP) | VAF 103/508 reads (20%) | called by muse, mutect2, varscan2
- OFD1 | c.*46C>T | 3'UTR (SNP) | VAF 68/328 reads (21%) | catalogued as rs1280404969, COSV57422526; called by muse, mutect2, varscan2
- TBC1D9B | c.*867G>T | 3'UTR (SNP) | VAF 124/462 reads (27%) | called by muse, mutect2, varscan2
- TG | c.-10G>A | 5'UTR (SNP) | VAF 168/827 reads (20%) | called by muse, mutect2, varscan2
- VCX3B | c.-10G>A | 5'UTR (SNP) | VAF 96/788 reads (12%) | catalogued as rs373991173; called by muse, varscan2
- ZNF853 | c.-11G>A | 5'UTR (SNP) | VAF 79/346 reads (23%) | catalogued as COSV101499538; called by muse, mutect2, varscan2
